Surgical pathology report (de-identified scan), TCGA case TCGA-85-8580, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8580-01A (Primary Tumor).

[page 1 of 4]
Case ID	Gross Description
	A. "Station 10." A 0.6 x 0.4 x 0.2 cm anthracotic lymph node. B. "Station 7." A 2.0 x 1.6 x 1.0 cm aggregate of anthracotic lymph nodes. C. "Station 11." A 0.7 x 0.5 x 0.4 cm aggregate D. "Right lower lobe with en bloc wedge of upper lobe marked by long stitch." A 278 gram, 18.0 x 14.0 x 4.0 cm right lower lobe and attached 5.5 x 3.0 x 2.5 cm portion of upper lobe wedge with suture at the surgical margin. There is a 3.7 x 3.0 cm mass that extends possibly through the pleura, crosses the fissure into the right upper lobe and is located approximately 0.5 cm from this stapled margin (inked black), 3.0 cm from the bronchial margin. There are two additional stapled margins 3.0 and 5.0 cm adjacent to the bronchial margin on the right lower lobe. The remaining parenchyma is unremarkable. E. "Station 4." A 1.2 x 0.5 x 0.5 cm and a 2.5 x 1.5 x 1.0 cm anthracotic lymph node.

[page 2 of 4]
Microscopic Description	Diagnosis Details
Tumor site: Right lower and upper lobes Tumor size: 3.7 cm Bronchial margin: Uninvolved (more than 1 cm free) Right upper lobe stapled margin: Uninvolved (4 mm free) Vascular margin: Uninvolved Visceral pleura: Involved by tumor Lymphovascular invasion: absent Treatment effect: Not applicable Other findings: Emphysematous changes. Atelectasis. Lymph nodes: main specimen (D): Not involved (1node) Station 4 (E): Not involved (2 nodes) Station 7 (B): Not involved (9 nodes) Station 10 (A): Not involved (1 node) Station 11 (C) : Not involved (3 nodes) Pathologic stage: pT2a N0 MX 	Squamous cell carcinoma without lymph nodal metastases

[page 3 of 4]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 3.7 x 3 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Visceral pleura Other tumor nodules: Not specified Lymph nodes: 0/16 positive for metastasis (Stations 4,7,10,11 0/16) Lymphatic invasion: Absent Venous invasion: Absent Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- lower

[page 4 of 4]
[REDACTED] ID	Excision date
[REDACTED]	[REDACTED]
[REDACTED]	[REDACTED]

Source: NCI Genomic Data Commons file 82d0a206-89ee-4ff6-a373-3b4a64a65c2d (TCGA-85-8580.2F5077B2-40FA-4BB6-8AEA-FF2E8DE682A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).